Somatic mutation profile of tumor specimen MMRF_2634_1_BM_CD138pos (aliquot MMRF_2634_1_BM_CD138pos_T1_KHS5U_L13307) from MMRF case MMRF_2634, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 59.7 years (21,812 days).
Specimen MMRF_2634_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 631f2165-957c-4b6d-abc7-29c3a893aa90.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2634_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2634_1_PB_WBC_C3_KHS5U_L13306; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4a24dafe-826b-4fe1-bd7b-5a4fe0d1dfd2

The open-access MAF lists 103 somatic variants for this specimen: 41 protein-altering or splice-affecting, 11 silent, 51 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, 3'UTR 24, Intron 12, Silent 11, 5'UTR 7, 3'Flank 4, 5'Flank 4, Splice Site 3, Frame Shift Del 2, Nonsense Mutation 2, Splice Region 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCDC7 | c.3019G>A p.D1007N | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.982); catalogued as rs370859338; called by muse, mutect2, varscan2
- DPYSL4 | c.875G>A p.S292N | Missense Mutation (SNP) | VAF 139/367 reads (38%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.965); catalogued as rs1465809779; called by muse, mutect2, varscan2
- DZIP1L | c.240C>A p.D80E | Missense Mutation (SNP) | VAF 81/172 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1367790486; called by muse, mutect2, varscan2
- FAAH | c.1682G>C p.C561S | Missense Mutation (SNP) | VAF 100/221 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54545210; called by muse, mutect2, varscan2
- HSP90B1 | c.2332G>A p.E778K | Missense Mutation (SNP) | VAF 37/249 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.027); catalogued as rs760087578, COSV55354186; called by muse, mutect2, varscan2
- IGHV1-69D | c.155C>T p.A52V | Missense Mutation (SNP) | VAF 59/122 reads (48%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs1367696485; called by muse, varscan2
- IGHV2-70 | c.229G>A p.D77N | Missense Mutation (SNP) | VAF 67/151 reads (44%) | SIFT tolerated (0.31); PolyPhen benign (0.072); catalogued as rs369066675; called by muse, varscan2
- IGHV2-70 | c.222G>A p.W74* | Nonsense Mutation (SNP) | VAF 55/144 reads (38%) | catalogued as rs371179860; called by muse, varscan2
- LTF | c.1217G>A p.G406E | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs747659801; called by muse, mutect2, varscan2
- MRPL1 | c.558+2T>A p.X186_splice | Splice Site (SNP) | VAF 31/70 reads (44%) | catalogued as COSV59675582; called by muse, mutect2, varscan2
- RALGDS | c.220G>A p.G74R | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs763512643; called by muse, mutect2, varscan2
- ZNF618 | c.1901G>A p.R634H (on ENST00000374126 / NM_001318042.2; = p.R541H on NM_133374.2) | Missense Mutation (SNP) | VAF 17/282 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs373497412; called by muse, mutect2
- AC009053.1 | n.938C>A | Splice Region (SNP) | VAF 49/128 reads (38%) | called by muse, mutect2, varscan2
- AGBL1 | c.1580T>C p.F527S | Missense Mutation (SNP) | VAF 58/138 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- CCDC96 | c.1037G>A p.R346Q | Missense Mutation (SNP) | VAF 124/332 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- CNGA3 | c.1741A>G p.K581E | Missense Mutation (SNP) | VAF 114/320 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CROCC2 | c.4486C>A p.L1496M | Missense Mutation (SNP) | VAF 39/75 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAH10 | c.9374T>A p.L3125Q (on ENST00000409039; = p.L3064Q on NM_207437.3) | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- G3BP2 | c.568G>T p.E190* | Nonsense Mutation (SNP) | VAF 23/56 reads (41%) | called by muse, mutect2, varscan2
- GRID1 | c.1837T>G p.Y613D | Missense Mutation (SNP) | VAF 51/156 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HRC | c.1432A>T p.R478W | Missense Mutation (SNP) | VAF 98/227 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- IGHV1-69D | c.214C>T p.P72S | Missense Mutation (SNP) | VAF 100/168 reads (60%) | SIFT tolerated (0.09); PolyPhen benign (0.259); called by muse, varscan2
- IGHV2-70D | c.262C>T p.L88F | Missense Mutation (SNP) | VAF 38/57 reads (67%) | SIFT tolerated (0.06); PolyPhen benign (0.438); called by muse, varscan2
- IL6ST | c.813+1G>T p.X271_splice | Splice Site (SNP) | VAF 7/21 reads (33%) | called by muse, mutect2, varscan2
- NLRP11 | c.2250A>C p.K750N | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- OPN4 | c.1186C>G p.H396D | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.01); called by muse, mutect2
- OR11A1 | c.503G>A p.R168K | Missense Mutation (SNP) | VAF 43/100 reads (43%) | SIFT tolerated (0.38); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- OTOA | c.2426C>T p.S809F (on ENST00000286149; = p.S795F on NM_144672.4) | Missense Mutation (SNP) | VAF 11/118 reads (9%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- OTX2 | c.598G>A p.D200N (on ENST00000408990 / NM_172337.3; = p.D208N on NM_021728.4) | Missense Mutation (SNP) | VAF 24/266 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.817); called by muse, mutect2
- PCDH11X | c.2859A>T p.E953D | Missense Mutation (SNP) | VAF 16/414 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.405); called by muse, mutect2
- PDE4D | c.419G>A p.R140K | Missense Mutation (SNP) | VAF 7/140 reads (5%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.039); called by muse, mutect2
- PIWIL3 | c.1269A>T p.K423N | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT tolerated (0.51); PolyPhen benign (0.017); called by muse, mutect2
- PRPF38B | c.1075_1078del p.E359Mfs*39 | Frame Shift Del (DEL) | VAF 50/156 reads (32%) | called by pindel, varscan2
- RBM6 | c.1561del p.T521Lfs*2 | Frame Shift Del (DEL) | VAF 34/386 reads (9%) | called by mutect2, pindel
- RNF19B | c.563A>G p.Y188C | Missense Mutation (SNP) | VAF 121/297 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- SEMA5B | c.2033C>T p.T678M | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SLC22A9 | c.1115T>C p.V372A | Missense Mutation (SNP) | VAF 37/126 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.279); called by muse, mutect2, varscan2
- SLC2A13 | c.716+1G>A p.X239_splice | Splice Site (SNP) | VAF 45/124 reads (36%) | called by muse, mutect2, varscan2
- SRF | c.1246A>T p.M416L | Missense Mutation (SNP) | VAF 51/157 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- YAF2 | c.306-8A>G | Splice Region (SNP) | VAF 50/119 reads (42%) | called by muse, mutect2, varscan2
- ZNF804A | c.1909C>A p.P637T | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACAD9 | c.315G>C p.G105= | Silent (SNP) | VAF 63/168 reads (38%) | called by muse, mutect2, varscan2
- ALOXE3 | c.1950G>A p.K650= | Silent (SNP) | VAF 41/99 reads (41%) | catalogued as rs1454136671; called by muse, mutect2, varscan2
- FAT4 | c.6288G>A p.K2096= | Silent (SNP) | VAF 120/280 reads (43%) | called by muse, mutect2, varscan2
- HHIPL2 | c.1233C>T p.P411= | Silent (SNP) | VAF 14/112 reads (13%) | catalogued as rs979592834, COSV100596576; called by muse, mutect2, varscan2
- HSBP1 | c.159G>A p.A53= | Silent (SNP) | VAF 22/42 reads (52%) | catalogued as rs1435096428, COSV71139201; called by muse, mutect2, varscan2
- IGHV2-70 | c.177T>G p.R59= | Silent (SNP) | VAF 58/152 reads (38%) | catalogued as rs572556497; called by muse, varscan2
- IGLV3-25 | c.66G>A p.E22= | Silent (SNP) | VAF 67/133 reads (50%) | catalogued as rs376421895; called by muse, mutect2, varscan2
- LRRC14B | c.468C>G p.V156= | Silent (SNP) | VAF 33/54 reads (61%) | called by muse, mutect2, varscan2
- MOG | c.21C>T p.P7= | Silent (SNP) | VAF 44/87 reads (51%) | called by muse, mutect2, varscan2
- PAQR9 | c.636G>A p.L212= | Silent (SNP) | VAF 5/107 reads (5%) | called by muse, mutect2
- RCSD1 | c.408G>A p.E136= | Silent (SNP) | VAF 78/172 reads (45%) | called by muse, varscan2
- ABHD11 | c.*107G>A | 3'UTR (SNP) | VAF 29/71 reads (41%) | called by muse, mutect2, varscan2
- ACTG1 | c.-1A>G | 5'UTR (SNP) | VAF 182/468 reads (39%) | catalogued as rs781801921; ClinVar: uncertain significance; called by muse, varscan2
- ACTG1 | c.-66G>A | 5'UTR (SNP) | VAF 116/276 reads (42%) | called by muse, varscan2
- ATE1 | c.*2920C>T | 3'UTR (SNP) | VAF 6/82 reads (7%) | called by muse, mutect2
- ATP8B4 | c.*969T>G | 3'UTR (SNP) | VAF 37/93 reads (40%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122020999 A>G | 5'Flank (SNP) | VAF 76/175 reads (43%) | called by muse, mutect2, varscan2
- C11orf87 | c.*4197dup | 3'UTR (INS) | VAF 31/72 reads (43%) | called by mutect2, pindel, varscan2
- CBX8 | c.*1354C>T | 3'UTR (SNP) | VAF 8/158 reads (5%) | called by muse, mutect2
- CHTOP | c.403+97A>G | Intron (SNP) | VAF 9/26 reads (35%) | called by muse, mutect2, varscan2
- CMTM6 | c.-60T>A | 5'UTR (SNP) | VAF 11/52 reads (21%) | called by mutect2, varscan2
- COLGALT2 | c.1137-869A>C | Intron (SNP) | VAF 14/152 reads (9%) | called by muse, mutect2
- DMRT1 | c.*289C>A | 3'UTR (SNP) | VAF 17/44 reads (39%) | called by muse, mutect2, varscan2
- FAM170B | c.*285G>T | 3'UTR (SNP) | VAF 64/163 reads (39%) | called by muse, mutect2, varscan2
- GLYR1 | c.*242C>G | 3'UTR (SNP) | VAF 92/126 reads (73%) | called by muse, mutect2, varscan2
- GMEB1 | chr1:28718087 A>T | 3'Flank (SNP) | VAF 30/61 reads (49%) | called by muse, mutect2, varscan2
- GRK4 | c.52+2659G>A | Intron (SNP) | VAF 18/41 reads (44%) | catalogued as rs973611189; called by muse, mutect2, varscan2
- GSG1L2 | c.511+15C>T | Intron (SNP) | VAF 22/54 reads (41%) | called by muse, mutect2, varscan2
- IFRD1 | c.409+218G>A | Intron (SNP) | VAF 15/115 reads (13%) | called by muse, mutect2, varscan2
- INTS7 | c.-27T>A | 5'UTR (SNP) | VAF 84/206 reads (41%) | called by muse, mutect2, varscan2
- ITPKB | c.*527G>A | 3'UTR (SNP) | VAF 25/527 reads (5%) | called by muse, mutect2
- KIFC3 | c.*170G>C | 3'UTR (SNP) | VAF 15/490 reads (3%) | called by muse, mutect2
- LMCD1 | c.723+1235G>A | Intron (SNP) | VAF 6/78 reads (8%) | catalogued as rs1051749763; called by muse, mutect2
- LONRF2 | c.*100G>T | 3'UTR (SNP) | VAF 71/192 reads (37%) | called by muse, mutect2, varscan2
- LRP5 | c.1801+459G>A | Intron (SNP) | VAF 5/10 reads (50%) | called by muse, mutect2
- LRRC27 | chr10:132376759 G>T | 3'Flank (SNP) | VAF 39/90 reads (43%) | catalogued as rs1174709087; called by muse, mutect2, varscan2
- LUZP2 | c.*3459G>A | 3'UTR (SNP) | VAF 29/67 reads (43%) | called by muse, mutect2, varscan2
- MACROD2 | chr20:13995452 C>T | 5'Flank (SNP) | VAF 13/21 reads (62%) | called by muse, mutect2, varscan2
- MAD1L1 | c.1999-33348A>T | Intron (SNP) | VAF 6/88 reads (7%) | called by muse, mutect2
- MEIS2 | c.-744G>A | 5'UTR (SNP) | VAF 46/104 reads (44%) | catalogued as rs1286154560; called by muse, mutect2, varscan2
- MICALL1 | c.*279G>A | 3'UTR (SNP) | VAF 64/162 reads (40%) | called by muse, mutect2, varscan2
- NCAM2 | c.*1307A>C | 3'UTR (SNP) | VAF 15/36 reads (42%) | called by muse, mutect2, varscan2
- NISCH | c.1528+1332C>A | Intron (SNP) | VAF 15/223 reads (7%) | called by muse, mutect2
- NTRK3 | chr15:87874525 C>T | 3'Flank (SNP) | VAF 65/164 reads (40%) | called by muse, mutect2, varscan2
- PARD6B | c.*429G>A | 3'UTR (SNP) | VAF 15/30 reads (50%) | called by muse, mutect2, varscan2
- PSMA6 | c.-48G>A | 5'UTR (SNP) | VAF 43/103 reads (42%) | called by muse, mutect2, varscan2
- RAP2B | c.*1728G>A | 3'UTR (SNP) | VAF 32/70 reads (46%) | called by muse, mutect2, varscan2
- RNF144B | c.*2417dup | 3'UTR (INS) | VAF 18/40 reads (45%) | catalogued as rs561516826; called by mutect2, varscan2
- RTF1 | c.1204-27G>T | Intron (SNP) | VAF 71/155 reads (46%) | called by muse, mutect2, varscan2
- SEL1L3 | chr4:25863487 G>A | 5'Flank (SNP) | VAF 138/340 reads (41%) | called by muse, mutect2, varscan2
- SEL1L3 | chr4:25863488 G>A | 5'Flank (SNP) | VAF 135/334 reads (40%) | called by muse, mutect2, varscan2
- SELL | c.*375C>A | 3'UTR (SNP) | VAF 35/85 reads (41%) | called by muse, mutect2, varscan2
- SHROOM4 | c.*997+503A>G | Intron (SNP) | VAF 13/51 reads (25%) | called by muse, mutect2, varscan2
- SPANXB1 | c.-62C>A | 5'UTR (SNP) | VAF 24/928 reads (3%) | called by muse, mutect2
- SRI | c.*1151A>G | 3'UTR (SNP) | VAF 46/117 reads (39%) | called by muse, mutect2, varscan2
- THRB | c.*4234A>C | 3'UTR (SNP) | VAF 5/93 reads (5%) | called by muse, mutect2
- TKTL2 | c.*205A>G | 3'UTR (SNP) | VAF 38/95 reads (40%) | called by muse, mutect2, varscan2
- TPPP | c.*3384C>T | 3'UTR (SNP) | VAF 28/160 reads (18%) | catalogued as rs915815115; called by muse, mutect2
- UBXN2A | c.*2551T>A | 3'UTR (SNP) | VAF 29/59 reads (49%) | called by mutect2, varscan2
- YAF2 | c.*720T>A | 3'UTR (SNP) | VAF 21/45 reads (47%) | called by muse, mutect2, varscan2
- ZNF268 | chr12:133205611 T>G | 3'Flank (SNP) | VAF 24/45 reads (53%) | called by muse, mutect2, varscan2
- ZNF385D | c.277-723A>G | Intron (SNP) | VAF 11/178 reads (6%) | called by muse, mutect2
